Somatic mutation profile of tumor specimen 0DGWOG from CCDI case PBBTMJ, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Vital status: Alive; Primary diagnosis: Ewing sarcoma; Tissue or organ of origin: Abdomen, NOS; Age at diagnosis: 16.4 years (5,984 days).
Specimen 0DGWOG: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) cfb0a5bf-36c6-4736-9afb-d7b84cad5b27.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DGWO9 (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/fd23b209-e24d-43c2-892b-aec2b4ab03c3

The open-access MAF lists 17 somatic variants for this specimen: 11 protein-altering or splice-affecting, 3 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 7, Silent 3, Frame Shift Del 2, Intron 2, 5'UTR 1, Splice Region 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- IFT80 | c.1000C>T p.R334C | Missense Mutation (SNP) | VAF 249/800 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as rs1249304164, COSV100425177; called by muse, mutect2, varscan2
- LRP1B | c.12997G>A p.E4333K | Missense Mutation (SNP) | VAF 230/735 reads (31%) | SIFT tolerated (0.32); PolyPhen benign (0); catalogued as COSV67189793; called by muse, mutect2
- MAPK8IP2 | c.191G>A p.R64H | Missense Mutation (SNP) | VAF 140/366 reads (38%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.939); catalogued as rs1424439283, COSV99151227; called by muse, mutect2, varscan2
- WDR93 | c.1403C>T p.S468L | Missense Mutation (SNP) | VAF 154/534 reads (29%) | SIFT tolerated (0.7); PolyPhen benign (0); catalogued as rs368092361, COSV51534237; called by muse, mutect2, varscan2
- AFF2 | c.2935del p.A979Hfs*64 | Frame Shift Del (DEL) | VAF 180/672 reads (27%) | called by mutect2, varscan2
- CACNA1F | c.3853G>T p.E1285* | Nonsense Mutation (SNP) | VAF 103/633 reads (16%) | called by muse, mutect2, varscan2
- COL19A1 | c.1892C>G p.T631R | Missense Mutation (SNP) | VAF 91/325 reads (28%) | SIFT tolerated (0.21); PolyPhen benign (0.305); called by muse, mutect2, varscan2
- HLTF | c.2692C>G p.Q898E | Missense Mutation (SNP) | VAF 30/1056 reads (3%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.947); called by muse, mutect2
- MGA | c.3416del p.K1139Rfs*3 | Frame Shift Del (DEL) | VAF 84/282 reads (30%) | called by mutect2, varscan2
- RRM1 | c.1470+4T>C | Splice Region (SNP) | VAF 89/300 reads (30%) | called by muse, mutect2, varscan2
- TMPRSS15 | c.787C>A p.L263I | Missense Mutation (SNP) | VAF 50/506 reads (10%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.544); called by muse, mutect2
- CD1D | c.999C>T p.G333= | Silent (SNP) | VAF 172/631 reads (27%) | catalogued as rs1473349997, COSV63809340; called by muse, mutect2, varscan2
- INPPL1 | c.2634C>A p.R878= | Silent (SNP) | VAF 184/517 reads (36%) | catalogued as COSV99996621; called by muse, mutect2, varscan2
- PCDHB12 | c.2094G>A p.S698= | Silent (SNP) | VAF 35/115 reads (30%) | called by muse, mutect2, varscan2
- CALCOCO2 | c.825+76T>A | Intron (SNP) | VAF 10/96 reads (10%) | called by muse, varscan2
- IRF3 | c.337+35G>A | Intron (SNP) | VAF 34/222 reads (15%) | called by muse, mutect2, varscan2
- MYL3 | c.-51C>T | 5'UTR (SNP) | VAF 79/229 reads (34%) | catalogued as rs894385728; called by muse, mutect2, varscan2
